Somatic mutation profile of tumor specimen ALCH-B572-TTP1-B (aliquot ALCH-B572-TTP1-B-1-0-D-A85H-36) from ALCHEMIST case ALCH-B572, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: male; Primary diagnosis: Adenocarcinoma, NOS; Age at diagnosis: 73.3 years (26,777 days).
Specimen ALCH-B572-TTP1-B: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 209053ac-5cde-4d95-827a-a460aee996e7.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen ALCH-B572-NB1-A (Blood Derived Normal), aliquot ALCH-B572-NB1-A-1-0-D-A85H-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/2fa71738-4809-4d38-bf7a-a0e1cad89821

The open-access MAF lists 24 somatic variants for this specimen: 17 protein-altering or splice-affecting, 6 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 15, Silent 6, Nonsense Mutation 2, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- ACTN2 | c.1645G>A p.E549K | Missense Mutation (SNP) | VAF 12/235 reads (5%) | SIFT tolerated (0.14); PolyPhen benign (0.23); catalogued as COSV100857127; called by muse, mutect2
- C6orf118 | c.776G>T p.C259F | Missense Mutation (SNP) | VAF 15/66 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.98); catalogued as COSV57819996; called by muse, mutect2, varscan2
- DSCAML1 | c.5971C>T p.R1991W (on ENST00000321322; = p.R1931W on NM_020693.4) | Missense Mutation (SNP) | VAF 11/135 reads (8%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.965); catalogued as rs779018567; called by muse, mutect2
- EIF4G1 | c.640G>T p.G214C (on ENST00000346169 / NM_198241.3; = p.G18C on NM_004953.5) | Missense Mutation (SNP) | VAF 19/150 reads (13%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.482); catalogued as COSV59988699; called by muse, mutect2, varscan2
- MYH14 | c.592G>A p.G198R | Missense Mutation (SNP) | VAF 8/113 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs1375962664; called by muse, mutect2
- PAX8 | c.530G>A p.G177D | Missense Mutation (SNP) | VAF 21/93 reads (23%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs201419236; called by muse, mutect2, varscan2
- PAXBP1 | c.2605G>A p.G869R | Missense Mutation (SNP) | VAF 5/75 reads (7%) | SIFT tolerated (0.06); PolyPhen probably damaging (0.945); catalogued as rs867702535; called by muse, mutect2
- PHKA1 | c.3349C>T p.R1117C | Missense Mutation (SNP) | VAF 33/280 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.953); catalogued as rs782021614, COSV59803683; called by muse, mutect2, varscan2
- ADA | c.787C>T p.P263S | Missense Mutation (SNP) | VAF 18/127 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- ADAMTSL5 | c.371A>T p.Q124L | Missense Mutation (SNP) | VAF 4/30 reads (13%) | SIFT tolerated (0.31); PolyPhen benign (0); called by mutect2, varscan2
- CNOT3 | c.1040C>A p.A347E | Missense Mutation (SNP) | VAF 3/15 reads (20%) | SIFT tolerated (0.13); PolyPhen benign (0.001); called by muse, varscan2
- CYP20A1 | c.1333G>A p.E445K | Missense Mutation (SNP) | VAF 18/230 reads (8%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.742); called by muse, mutect2
- MEGF10 | c.2952G>A p.W984* | Nonsense Mutation (SNP) | VAF 13/135 reads (10%) | called by muse, mutect2
- MEIS2 | c.788G>A p.G263D (on ENST00000561208 / NM_170675.5; = p.G250D on NM_002399.3) | Missense Mutation (SNP) | VAF 14/200 reads (7%) | SIFT tolerated (0.09); PolyPhen benign (0.015); called by muse, mutect2
- SUCO | c.2438C>T p.S813F | Missense Mutation (SNP) | VAF 8/147 reads (5%) | SIFT deleterious (0.03); PolyPhen benign (0.326); called by muse, mutect2
- TP53BP1 | c.151C>T p.Q51* | Nonsense Mutation (SNP) | VAF 8/106 reads (8%) | called by muse, mutect2
- TTN | c.16906T>C p.F5636L (on ENST00000591111; = p.F4709L on NM_133378.4 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 9/205 reads (4%) | PolyPhen benign (0.003); called by muse, mutect2
- ALDH1L2 | c.612C>G p.L204= | Silent (SNP) | VAF 13/155 reads (8%) | called by muse, mutect2
- C6orf118 | c.777C>T p.C259= | Silent (SNP) | VAF 15/67 reads (22%) | catalogued as rs142987333, COSV57817243; called by muse, mutect2, varscan2
- FGFBP1 | c.516G>A p.E172= | Silent (SNP) | VAF 4/34 reads (12%) | catalogued as rs376624573; called by mutect2, varscan2
- TAF7 | c.738C>T p.I246= | Silent (SNP) | VAF 17/230 reads (7%) | catalogued as rs1462988522; called by muse, mutect2
- UCP1 | c.141C>T p.C47= | Silent (SNP) | VAF 16/282 reads (6%) | called by muse, mutect2
- UMPS | c.438C>T p.V146= | Silent (SNP) | VAF 13/353 reads (4%) | catalogued as COSV99228777; called by muse, mutect2
- B4GALNT1 | c.*2835G>T | 3'UTR (SNP) | VAF 7/76 reads (9%) | called by muse, mutect2
